Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAN1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAN1-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

DIAGNOSIS:

RADICAL CYSTECTOMY, HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY, BILATERAL PELVIC LYMPH NODE DISSECTION, ILEAL CONDUIT DIVERSION, REPAIR UMBILICAL HERNIA AND GASTROSTOMY TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER, UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES (C):

BLADDER, UTERUS:

- INVASIVE PAPILLARY UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/4, MULTIFOCAL
- TUMOR INVADES DEEP MUSCLE (OUTER HALF)
- TUMOR INVADES URETHRA AND VAGINA (NO MUCOSAL INVOLVEMENT IDENTIFIED)
- MULTIFOCAL PAPILLARY UROTHELIAL CARCINOMA, NUCLEAR GRADE 3/4, NON-INVASIVE
- ALL SURGICAL MARGINS, FREE OF TUMOR
- NO VASCULAR OR PERINEURAL INVASION IDENTIFIED
- ATROPHIC ENDOMETRIUM
- CHRONIC CERVICITIS

BILATERAL OVARIES AND FALLOPIAN TUBES:

- NO TUMOR IDENTIFIED

UMBILICAL HERNIA SAC (D):

- HERNIA SAC

RIGHT NODE OF CLOQUET (E):

- NO TUMOR IDENTIFIED IN FOUR LYMPH NODE (0/4)

RIGHT EXTERNAL ILIAC LYMPH NODES (F):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES (0/7)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (G):

- NO TUMOR IDENTIFIED IN 11 LYMPH NODES (0/11)

LEFT NODE OF CLOQUET (H):

- NO TUMOR IDENTIFIED IN TWO LYMPH NODES (0/2)

LEFT EXTERNAL ILIAC LYMPH NODES (I):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES (0/7)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (J):

- NO TUMOR IDENTIFIED IN 15 LYMPH NODES (0/15)

RIGHT PERISCIATIC LYMPH NODES (K):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1)

ICD-O-3
Carcinoma, papillary urothelial
8130/3
Site: Bladder NOS
C67.9
JW 3/26/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

LEFT PRESACRAL LYMPH NODES (L):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES (0/3)

PRESACRAL LYMPH NODES (M):

- NO TUMOR IDENTIFIED IN THREE LYMPH NODES (0/3)

RIGHT PROXIMAL URETER [MARGIN] (N):

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT PROXIMAL URETER [MARGIN] (O):

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

OMENTUM (P):

- NO TUMOR IDENTIFIED

ADDITIONAL UMBILICAL HERNIA SAC (Q):

- HERNIA SAC

LYMPH NODE SUMMARY: NO TUMOR IDENTIFIED IN TOTAL OF 53 LYMPH NODES
EXAMINED (0/53)

PATHOLOGIC TNM STAGE: pT4aN0MX

Electronically signed by
Verified:

COMMENT:

Immunohistochemical studies for p53 assay has been ordered, results of which will be reported in an addendum.

SPECIMEN SOURCE:

- A: "Right distal ureter - F/S"
- B: "Left distal ureter - F/S"
- C: "Bladder uterus, bilat. tubes & ovaries"
- D: "Umbilical hernia sac"
- E: "R node of cloquet"
- F: "R. external iliac lymph nodes"
- G: "R obturator/hypogastric L. nodes"
- H: "L node of cloquet"
- I: "L external iliac lymph nodes"
- J: "L obturator/hypogastric L. nodes"
- K: "R presciatic L. nodes"
- L: "L. presciatic L. node"
- M: "Presacral L. nodes"
- N: "R. proximal ureter (margin)"
- O: "L. proximal ureter (margin)"
- P: "Omentum"
- Q: "Additional umbilical hernia sac"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer and umbilical hernia
Post-op Dx: Same

GROSS EXAMINATION:

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Collected: _____
Ordered by: _____

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter - F/S". It consists of a single fragment of tan tissue dimensions are not provided. The specimen is entirely submitted for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter - F/S". It consists of a single fragment of tan tissue dimensions are not provided. The specimen is entirely submitted for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder uterus, bilat. tubes & ovaries". It consists of a radical cystectomy, hysterectomy with bilateral salpingo oophorectomy specimen measuring overall 18 x 15 x 5 cm. A flap of peritoneal fat is present and measures 10 x 5 x 1 cm. Attached is a bladder measuring 7 x 6 x 3 cm and the uterus measures 6 x 3.5 x 2 cm. The outer surface of the specimen is inked black. The bladder is opened longitudinally. Opening the specimen reveal multiple masses attached to the dome of the bladder, right lateral wall, left lateral wall, anterior wall and the right ureterovesical junction. The largest mass measures 3 cm in greatest dimension. The outer surface of the masses is tan, irregular and slightly lobulated. The different tumor does not appear to invade the underlying soft tissue and the fat grossly. Also sectioning through the tumor reveal predominantly mural involvement with a freely mobile, grossly unremarkable perivesical fat. The surrounding retroperitoneal margin is grossly free of tumor. The adjacent urethral surfaces show tan, urethral mucosa with no other discreet nodule grossly identified. The right distal ureter is dilated and measures 4 cm in length x 1.8 cm in circumference. The left distal ureter measures 3.5 cm in length x 0.5 cm in circumference and is grossly unremarkable. The urethral mucosa of both the right and left ureters are grossly unremarkable. Attached to the posterior bladder is a large strip of vaginal mucosa measuring 7 x 2.8 x 0.2 cm. The vaginal mucosa is tan, smooth and grossly unremarkable. The attached uterus and cervix measures overall 6 x 3.5 x 2 cm. The uterine cavity measures 2.5 x 2 x 1 cm and is grossly unremarkable. The endometrium is tan, smooth and measures 0.2 cm in thickness. The myometrium is tan and measures 0.8 cm in thickness. No intracavitary lesion is identified. The cervix measures 2 cm in length x 1 cm in diameter. The endocervical canal measures 1.5 cm in length x 1 cm in circumference. The endocervical mucosa is tan, smooth and glistening. The right fallopian tube measures 2 cm in length x 0.3 cm in diameter and is grossly unremarkable. The right ovary measures 1.5 x 0.5 x 0.5 cm and is grossly unremarkable. The left fallopian tube measures 2 cm in length x 0.4 cm in diameter and is grossly unremarkable. The left ovary measures 1.2 x 0.5 x 0.5 cm and is grossly unremarkable. Representative sections are submitted in 30 cassettes.

D: The specimen is received in formalin and labeled "Umbilical hernia sac". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 3 x 2 x 1 cm. Representative sections are submitted in two cassettes.

E: The specimen is received in formalin and labeled "R node of cloquet". It consists of a single fragment of tan fibroadipose tissue measuring 1 x 1 x 1 cm. The specimen is dissected and a single lymph node is identified measuring 1 cm in greatest diameter. The lymph node is bisected and entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "R. external iliac lymph nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 3 x 2 x 1 cm. The specimen is dissected for lymph nodes, a few lymph nodes are identified. The specimen is entirely submitted in four cassettes.

G: The specimen is received in formalin and labeled "R obturator/hypogastric L. nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 7 x 4 x 3 cm. The specimen is dissected for lymph nodes, several lymph nodes are identified. Representative sections are submitted in five

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Connected

Ordered by

cassettes.

H: The specimen is received in formalin and labeled "L node of cloquet". It consists of a single lymph node measuring 1 x 1 x 0.5 cm. The specimen is bisected and entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "L external iliac lymph nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 4 x 4 x 3 cm. The specimen is dissected for lymph nodes, several lymph nodes are identified. The specimen is entirely submitted in four cassettes.

J: The specimen is received in formalin and labeled "L obturator/hypogastric L. nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 5 x 5 x 4 cm. The specimen is dissected for lymph nodes, several lymph nodes are identified. Representative sections are submitted in five cassettes.

K: The specimen is received in formalin and labeled "R presciatic L. nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 1 x 1 x 1 cm. The specimen is entirely submitted in one cassette.

L: The specimen is received in formalin and labeled "L. presciatic L. node". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 1 x 1 x 1 cm. The specimen is entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Presacral L. nodes". It consists of multiple fragments of yellow-tan fibroadipose tissue measuring in aggregate 3 x 2 x 1 cm. The specimen is dissected for lymph nodes, several lymph nodes are identified. The specimen is entirely submitted in four cassettes.

N: The specimen is received in formalin and labeled "R. proximal ureter (margin)". It consists of a segment of ureter measuring 2 cm in length x 1 cm in diameter. Attached are three metallic staples. Representative sections are submitted from one end of the specimen in one cassette.

O: The specimen is received in formalin and labeled "L. proximal ureter (margin)". It consists of a segment of ureter measuring 1 cm in length x 0.5 cm in diameter. Attached is a single metallic staple. Representative sections are submitted in one cassette.

P: The specimen is received in formalin and labeled "Omentum". It consists of a single fragment of yellow-tan fibroadipose tissue measuring 8 x 4 x 3 cm. The outer surface of the specimen is yellow, smooth, lobulated and is grossly unremarkable. The specimen is serially sectioned and is grossly unremarkable. Representative sections are submitted in two cassettes.

Q: The specimen is received in formalin and labeled "Additional umbilical hernia sac". It consists of a single fragment of yellow-tan fibroadipose tissue measuring 2 x 1 x 1 cm. Representative sections are submitted in one cassette.

SECTIONS:

- AFS: frozen section, right distal ureter
- BFS: frozen section, left distal ureter
- C1: urethral margin
- C2: right ureter margin
- C3: left ureter margin
- C4: bladder neck and urethra
- C5: bladder neck
- C6-7: right urethral vesical junction and tumor

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

C8: left urethral vesical junction
C9: dome of bladder
C10: right lateral wall
C11: left lateral wall
C12: anterior wall
C13: posterior wall
C14-17: section of the different tumor
C18-21: deep inked margin of the tumor
C22: vaginal margin
C23: posterior cervix
C24: anterior cervix
C25: posterior endomyometrium
C26: anterior endomyometrium and serosa
C27: right fallopian tube and ovary
C28: left fallopian tube and ovary
C29-C30: perivesical fat
D1-2: umbilical hernia sac
E: right node of Cloquet, bisected
F1-4: right external iliac lymph nodes
G1-5: right obturator/hypogastric lymph nodes
H: lymph node of Cloquet, bisected
I1-4: left external iliac lymph nodes
J1-5: left obturator/hypogastric lymph nodes
K: right presciatic lymph nodes
L: left presciatic lymph nodes
M1-4: presacral lymph nodes
N: right proximal ureter (margin)
O: left proximal ureter (margin)
P1-2: omentum
Q: additional umbilical hernia sac

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- no tumor identified

BFS: Left distal ureter
- no tumor identified

Source: NCI Genomic Data Commons file f73caccf-a6be-44cf-8927-8d2548810a1d (TCGA-XF-AAN1.7BD47644-AADB-40AE-A5BA-997B74F6AD80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).